Somatic mutation profile of tumor specimen 1105196 (aliquot 7316UP-435-1105196) from CPTAC case C317832, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen 1105196: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2febb27-7cb6-4a96-824c-ad7c8dc9498f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105209 (Blood Derived Normal), aliquot 7316UP-435-1105209; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54151e07-be18-4cde-81fc-9a23ed125428

The open-access MAF lists 73 somatic variants for this specimen: 54 protein-altering or splice-affecting, 15 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 15, Frame Shift Del 5, Nonsense Mutation 4, 5'UTR 1, RNA 1, Splice Site 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 2741/4220 reads (65%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs104894229, CM053283, CM061797, COSV54236795, COSV54236828, COSV54237299; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.1693G>A p.D565N | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.454); catalogued as COSV101201270; called by muse, mutect2
- ABCC1 | c.1699G>A p.V567I | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs545772203, COSV60686964; called by muse, mutect2, varscan2
- ABTB1 | c.1159G>A p.V387M (on ENST00000232744 / NM_172027.3; = p.V245M on NM_032548.3) | Missense Mutation (SNP) | VAF 41/375 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs373702607; called by muse, mutect2, varscan2
- AL592490.1 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV69426315; called by muse, mutect2, varscan2
- AMBN | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.713); catalogued as rs144829376; called by muse, mutect2, varscan2
- CASP10 | c.1558G>A p.V520I | Missense Mutation (SNP) | VAF 50/341 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs141197114; called by muse, mutect2, varscan2
- CCDC85C | c.904G>A p.G302S | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1475770210; called by muse, mutect2, varscan2
- CD96 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1035836810, COSV51917150; called by muse, mutect2, varscan2
- CEACAM3 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.076); catalogued as rs781937332, COSV55763245; called by muse, mutect2, varscan2
- CFAP52 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs140921334; called by muse, mutect2
- COL3A1 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 74/449 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs1238066761, COSV58597103; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTR9 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs754637023, COSV63728462; called by muse, mutect2, varscan2
- DNAH11 | c.6005G>A p.R2002Q | Missense Mutation (SNP) | VAF 32/352 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs755849132; called by muse, mutect2
- GABRA6 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs759363086; called by muse, mutect2, varscan2
- GIN1 | c.1472C>A p.T491K | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.018); catalogued as COSV67537797; called by muse, varscan2
- GLRA3 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 19/162 reads (12%) | catalogued as rs766770260; called by muse, mutect2, varscan2
- GREB1L | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs371959545, COSV52552089; called by muse, mutect2, varscan2
- KCNT2 | c.2762G>T p.G921V | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54071255; called by muse, mutect2, varscan2
- KLF17 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 51/387 reads (13%) | catalogued as rs760187091; called by muse, mutect2, varscan2
- MARCKS | c.980del p.P327Qfs*42 | Frame Shift Del (DEL) | VAF 37/208 reads (18%) | catalogued as rs770972906; called by mutect2, pindel, varscan2
- MS4A12 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs111546873, COSV50014503; called by muse, mutect2, varscan2
- NAALADL1 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375401003; called by muse, mutect2, varscan2
- NEDD4 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs770359798, COSV59062162; called by muse, mutect2, varscan2
- NUTM2F | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 52/319 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.476); catalogued as rs550162263; called by muse, mutect2, varscan2
- PCDH11X | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.13); catalogued as rs761488640, COSV53438348; called by muse, mutect2, varscan2
- PCDHGB2 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 85/600 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53926229; called by muse, mutect2, varscan2
- RYR1 | c.10595T>A p.L3532H | Missense Mutation (SNP) | VAF 48/696 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748378336; called by muse, mutect2
- SCN10A | c.5376G>T p.L1792F | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1488076050; called by muse, mutect2, varscan2
- TMEM71 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 66/494 reads (13%) | catalogued as rs762484420, COSV100785481; called by muse, mutect2, varscan2
- VNN1 | c.424A>G p.K142E | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1340722953; called by muse, mutect2
- ADGRV1 | c.8770T>G p.L2924V | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- AJM1 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 33/288 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- ALPK3 | c.2000C>A p.A667E | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH11 | c.6581T>A p.M2194K | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- DNAH2 | c.9972C>A p.F3324L | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- FANCC | c.941C>G p.T314S | Missense Mutation (SNP) | VAF 96/593 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FLII | c.1851T>A p.Y617* | Nonsense Mutation (SNP) | VAF 25/197 reads (13%) | called by muse, mutect2, varscan2
- GPR149 | c.112del p.C38Afs*2 | Frame Shift Del (DEL) | VAF 50/396 reads (13%) | called by mutect2, pindel, varscan2
- IFRD2 | c.311C>A p.A104D | Missense Mutation (SNP) | VAF 83/445 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- KCNJ3 | c.1348A>C p.K450Q | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LRP1B | c.11058C>G p.C3686W | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC3 | c.397del p.L133Wfs*28 | Frame Shift Del (DEL) | VAF 21/193 reads (11%) | called by mutect2, varscan2
- MGRN1 | c.530A>G p.K177R | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- MYOCD | c.971+3_971+6del p.X324_splice | Splice Site (DEL) | VAF 29/172 reads (17%) | called by pindel, varscan2
- NPHS2 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 43/366 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10P1 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PALM | c.492G>A p.M164I | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- SCN11A | c.2696T>C p.I899T | Missense Mutation (SNP) | VAF 26/271 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2
- SLC12A9 | c.1405A>G p.M469V | Missense Mutation (SNP) | VAF 48/277 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- TNRC6B | c.5475del p.L1826Wfs*29 (on ENST00000454349 / NM_001162501.2; = p.L1716Wfs*29 on NM_015088.3) | Frame Shift Del (DEL) | VAF 19/156 reads (12%) | called by mutect2, pindel, varscan2
- TRBV19 | c.83del p.K28Sfs*11 | Frame Shift Del (DEL) | VAF 14/111 reads (13%) | called by mutect2, pindel, varscan2
- TTN | c.1843G>C p.V615L (on ENST00000591111; = p.V569L on NM_003319.4) | Missense Mutation (SNP) | VAF 27/260 reads (10%) | PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ZIC1 | c.298T>A p.F100I | Missense Mutation (SNP) | VAF 47/323 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CEACAM7 | c.120C>T p.V40= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs147314898; called by muse, mutect2, varscan2
- CHAT | c.1230C>T p.G410= | Silent (SNP) | VAF 42/228 reads (18%) | catalogued as rs779724822; called by muse, mutect2, varscan2
- DLX6 | c.300C>T p.Y100= | Silent (SNP) | VAF 25/224 reads (11%) | catalogued as rs1393099414; called by muse, varscan2
- DNMT3A | c.1707G>A p.P569= | Silent (SNP) | VAF 36/241 reads (15%) | catalogued as rs749106325, COSV53071322, COSV99262646; called by muse, mutect2, varscan2
- KPTN | c.462G>A p.G154= | Silent (SNP) | VAF 26/229 reads (11%) | catalogued as rs1347346115; called by muse, mutect2, varscan2
- KRTAP26-1 | c.261C>T p.Y87= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs765005253, COSV62128579, COSV62128769; called by muse, mutect2, varscan2
- OR10V1 | c.117C>T p.L39= | Silent (SNP) | VAF 26/232 reads (11%) | catalogued as rs778530423, COSV55700323; called by muse, mutect2, varscan2
- PAX4 | c.390A>G p.A130= | Silent (SNP) | VAF 75/644 reads (12%) | catalogued as rs756403936; called by muse, mutect2, varscan2
- RELN | c.1560G>A p.P520= | Silent (SNP) | VAF 43/307 reads (14%) | catalogued as rs41276157; called by muse, mutect2, varscan2
- RP1 | c.1641C>T p.L547= | Silent (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2, varscan2
- SLC43A1 | c.24G>A p.A8= | Silent (SNP) | VAF 40/243 reads (16%) | called by muse, mutect2, varscan2
- SLC45A3 | c.867G>A p.T289= | Silent (SNP) | VAF 20/135 reads (15%) | catalogued as rs768335329, COSV65654778; called by muse, mutect2, varscan2
- SMAD7 | c.522C>T p.V174= | Silent (SNP) | VAF 31/213 reads (15%) | catalogued as rs768564558; called by muse, mutect2, varscan2
- SRRM2 | c.465T>C p.R155= | Silent (SNP) | VAF 21/192 reads (11%) | catalogued as rs770078193; called by muse, mutect2, varscan2
- ZAN | c.5505G>A p.P1835= | Silent (SNP) | VAF 44/371 reads (12%) | catalogued as rs755450631, COSV100770515; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827971 C>T | 3'Flank (SNP) | VAF 16/55 reads (29%) | called by mutect2, varscan2
- RGS2 | c.-20dup | 5'UTR (INS) | VAF 60/445 reads (13%) | called by mutect2, pindel, varscan2
- SLC9A7P1 | n.364G>A | RNA (SNP) | VAF 61/350 reads (17%) | catalogued as rs763216666; called by muse, mutect2, varscan2
- TSHZ2 | c.*2000C>T | 3'UTR (SNP) | VAF 38/422 reads (9%) | called by muse, mutect2
